TCGA case TCGA-V4-A9EU — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df685f8c-645a-47ae-a471-63bf1973a0ae

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 83 years; Year of birth: 1928; Vital status: Dead; Days to death: 796 days (2.2 years); Year of death: 2014.

Diagnoses (3)
1. Epithelioid cell melanoma (the primary disease): ICD-O-3 morphology code: 8771/3; ICD-10 code: C69.40; Tissue or organ of origin: Ciliary body; Site of resection or biopsy: Ciliary body; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 83.3 years (30,409 days); Year of diagnosis: 2011; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4d; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIC; AJCC pathologic T: T4d; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 796 days (2.2 years); Sites of involvement: Eye, Choroid / Eye, Ciliary Body.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 20.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: >90%; Extraocular nodule size: <=5mm; Extrascleral extension present: Yes; Measurement type: Echographic; Tumor depth measurement: 11.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -15 days; Residual disease: R1; Treatment anatomic sites: Eye.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary of the biliary tract (histology not recorded by GDC). Age at diagnosis: 83.5 years (30,495 days); Days to diagnosis: 86 days; Prior treatment: Yes.
3. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; Tissue or organ of origin: Biliary tract, NOS; Classification of tumor: Subsequent Primary; Age at diagnosis: 83.5 years (30,495 days); Days to diagnosis: 86 days; Prior treatment: Yes.

Follow-up (2 entries)
- Days to follow up: 709 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 796 days (2.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 52 kg; Height: 154 cm; BMI: 21.9.
- Eye color: Green.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 55 mg.
  Slide TCGA-V4-A9EU-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Choroid.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: >90%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: biliary.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Biliary.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 709 days; disease-specific survival: no event (censored), 709 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 86 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EU-01A-11D-A39V-01): tumor purity 0.97, ploidy 2.06, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3; Gain 8q
- days to outcome: 76
- days to procedure 1: -15
- diagnosis: melanoma
- disease status at death: No Evidence of Disease
- disease status at last followup: 2nd cancer cholangio carcinoma
- icd 10: C69.30
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- outcome: Complete Response
- performance status scale: Karnofsky
- performance status score: 1
- resection status 1: R1
- smoking status: non-smoker
- staging system: AJCC
- t stage: T4d
- test methodology: aCGH
- test result: high risk
- tissue of origin: choroid
- unresectable 1: no
